Somatic mutation profile of tumor specimen TCGA-32-2615-01A (aliquot TCGA-32-2615-01A-01D-1495-08) from TCGA case TCGA-32-2615, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.7 years (22,916 days).
Specimen TCGA-32-2615-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a945715a-2885-45ce-95d9-cb584135bc32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2615-10A (Blood Derived Normal), aliquot TCGA-32-2615-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23d5c028-39f9-4bb5-8c18-377439391823

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 12, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP17A | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58312008; called by muse, mutect2
- AKR1C4 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.389); catalogued as COSV54125519; called by muse, mutect2, varscan2
- APOB | c.6034C>T p.R2012* | Nonsense Mutation (SNP) | VAF 83/215 reads (39%) | catalogued as rs147863759, CM962634; called by muse, mutect2, varscan2
- CLEC14A | c.1396G>T p.V466F | Missense Mutation (SNP) | VAF 72/105 reads (69%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV60564216; called by muse, mutect2, varscan2
- CPNE8 | c.643A>T p.I215F | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV58851799; called by muse, mutect2, varscan2
- CYP4F11 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200410691; called by muse, mutect2, varscan2
- DNAH17 | c.7001C>T p.T2334M | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs148973316; called by muse, mutect2, varscan2
- DPPA4 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 102/338 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs867198096, COSV59509181; called by muse, mutect2, varscan2
- EGR1 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1230522969, COSV53518023; called by muse, mutect2, varscan2
- GATB | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV56130473, COSV56133470; called by muse, mutect2, varscan2
- GRIP1 | c.1585G>A p.G529R (on ENST00000359742 / NM_001379345.1; = p.G477R on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54014803; called by muse, mutect2, varscan2
- IMPG1 | c.37dup p.W13Lfs*15 | Frame Shift Ins (INS) | VAF 31/59 reads (53%) | catalogued as rs1487703697; called by mutect2, pindel, varscan2
- ITIH3 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.107); catalogued as COSV56258403; called by muse, mutect2, varscan2
- KIF21A | c.2879G>T p.R960I (on ENST00000361418 / NM_001378440.1; = p.R947I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/373 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV62777937; called by muse, mutect2, varscan2
- NOBOX | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as rs753930313, COSV56197660; called by muse, mutect2, varscan2
- NUP54 | c.52A>C p.T18P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1457460682, COSV53577357; called by muse, mutect2
- OPN4 | c.630C>T p.S210= | Splice Region (SNP) | VAF 43/67 reads (64%) | catalogued as rs750708805, COSV54118607; called by muse, mutect2, varscan2
- OR2J3 | c.626T>C p.F209S | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV65849443, COSV65849664; called by muse, mutect2
- PCDHA3 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.606); catalogued as rs782724131, COSV63545865; called by muse, mutect2, varscan2
- PRSS16 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs145240806; called by muse, mutect2, varscan2
- R3HDML | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53837709; called by muse, mutect2, varscan2
- THSD7B | c.1844A>C p.Q615P | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); catalogued as COSV55735869; called by muse, mutect2, varscan2
- TNPO3 | c.2348C>T p.S783F | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV55286761; called by muse, mutect2, varscan2
- TPO | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs1327228715, COSV61111044; called by muse, mutect2, varscan2
- ULK1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV58859841; called by muse, mutect2, varscan2
- ZNF318 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 49/106 reads (46%) | catalogued as rs1031622523, COSV58930475; called by muse, mutect2, varscan2
- ASS1 | c.489C>T p.Y163= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs377319610; called by muse, mutect2, varscan2
- BOD1L1 | c.2973A>G p.R991= | Silent (SNP) | VAF 214/478 reads (45%) | catalogued as COSV50062544; called by muse, mutect2, varscan2
- CDKN2D | c.159C>T p.S53= | Silent (SNP) | VAF 52/215 reads (24%) | catalogued as COSV57265863; called by muse, mutect2, varscan2
- CPSF1 | c.1527C>T p.N509= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs371053206; called by muse, mutect2, varscan2
- HTR3A | c.429C>T p.G143= | Silent (SNP) | VAF 68/227 reads (30%) | catalogued as rs573001897, COSV55468053; called by muse, mutect2, varscan2
- KLHL1 | c.1737A>G p.Q579= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as rs752886574, COSV64783608; called by muse, mutect2, varscan2
- MAB21L3 | c.399C>T p.I133= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as rs1429094616, COSV65674556; called by muse, mutect2, varscan2
- PARP12 | c.894G>A p.P298= | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as rs147556524; called by muse, mutect2, varscan2
- SH3RF2 | c.1245C>T p.D415= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as rs561869294, COSV63041358; called by muse, mutect2, varscan2
- TAF3 | c.921A>G p.K307= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV60211543; called by muse, mutect2
- XKR4 | c.888A>G p.V296= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs1179174638, COSV59338592; called by muse, mutect2, varscan2
- ZIC3 | c.756G>A p.S252= | Silent (SNP) | VAF 52/66 reads (79%) | catalogued as COSV54975030; called by muse, mutect2, varscan2
- THRA | c.1110+60del | Intron (DEL) | VAF 33/74 reads (45%) | called by mutect2, pindel, varscan2
